Gene-level copy-number profile of tumor specimen HTMCP-03-06-02020-01A from CGCI case HTMCP-03-06-02020, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3afea92a-3ce9-43eb-a7fb-2c0839d14a5e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02020-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/d12b7379-7e0f-48ad-807e-03f7c321b020

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 2,025; copy number 2: 22,977; copy number 3: 27,433; copy number 4: 3,737; copy number 5: 907; copy number 6: 933; copy number 7: 75; copy number 8: 71; copy number 9: 34; copy number 10: 54; copy number 13: 63; copy number 15: 19; copy number 17: 3; copy number 23: 43.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,838,125–12,841,357, 1 gene: PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–3): PRAMEF2.
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr3:60,616,822–60,732,636, 5 genes (within-gene range 0–2): AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 362 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:96,859,718–97,051,028, 13 genes, copy number 7: SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2.
- chr3:163,455,568–164,171,556, 4 genes, copy number 7: AC079910.1, RNU7-82P, AC084017.1, MIR1263.
- chr3:165,772,904–178,937,352, 176 genes, copy number 7–15 (broad region; genes not listed).
- chr3:180,161,886–180,161,977, 1 gene, copy number 13: RNA5SP149.
- chr3:180,542,701–184,106,995, 82 genes, copy number 9–10 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 7: TRGC2.
- chr7:38,257,879–38,340,998, 14 genes, copy number 7: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes, copy number 7 (within-gene range 4–7): TRGV5P, TRGV5.
- chr11:73,157,946–73,298,625, 6 genes, copy number 8: AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6.
- chr11:97,878,475–102,903,953, 55 genes, copy number 8–23: LINC02713, AP003730.1, AP001317.1, AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P.
- chr16:10,326,434–10,580,632, 8 genes, copy number 7: ATF7IP2, AC131649.1, AC131649.2, RNU6-633P, LINC01290, EMP2, AC027277.1, AC027277.2.

Autosomal genes at a single copy (total copy number 1): 2,022. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
